CCDI case PBBZIA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b0dab175-f073-41d1-a32d-eff64727e142

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.1 years (4,046 days).

Biospecimens (3 samples)
- Sample 0DLFB0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLFBT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLFBV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
